Somatic mutation profile of tumor specimen MP2PRT-PAUVDR-TMP1-A (aliquot MP2PRT-PAUVDR-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAUVDR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (569 days).
Specimen MP2PRT-PAUVDR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb949096-d03c-4748-9cbc-3b3de700bf4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUVDR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUVDR-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6e09495-e734-44d1-b467-64acbe05db4d

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT3 | c.3629G>A p.R1210K | Missense Mutation (SNP) | VAF 64/315 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs1358011122, COSV53153658, COSV99968948; called by muse, mutect2, varscan2
- KLHL24 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 95/387 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1343188960; called by muse, mutect2, varscan2
- SLC27A6 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 105/510 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1234563727; called by muse, mutect2, varscan2
- TAF1D | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1188329059; called by muse, mutect2, varscan2
- C11orf52 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 138/556 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- CEP85 | c.1445A>G p.Y482C | Missense Mutation (SNP) | VAF 133/526 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRIN3A | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 250/1058 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SGSH | c.645C>T p.Y215= | Silent (SNP) | VAF 106/474 reads (22%) | catalogued as rs151227799; called by muse, mutect2, varscan2
- SPRY1 | c.333G>A p.L111= | Silent (SNP) | VAF 86/389 reads (22%) | called by muse, mutect2, varscan2
